MMRF case MMRF_1672 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e32bc34b-9732-4be4-b4dd-484ebcc57ff8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.8 years (21,116 days); ISS stage: III; Days to last known disease status: 1,195 days (3.3 years); Days to last follow up: 1,195 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 154 days; Days to treatment end: 536 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 536 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -30 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 500 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 4.01 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 11.3 µg/mL; Lactate Dehydrogenase 10.1 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 346 ×10⁹/L; Creatinine 433 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.85 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 6 mmol/L; C-Reactive Protein 0.44 mg/dL.
- Day 71 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.822 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.527 mg/dL; Immunoglobulin G 3.23 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.09 ×10⁹/L; Absolute Neutrophil 3.76 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 6.82 mmol/L.
- Day 154 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.994 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.772 mg/dL; Immunoglobulin G 4.53 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.46 ×10⁹/L; Absolute Neutrophil 3.23 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.65 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 257 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.43 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 2.53 ×10⁹/L; Absolute Neutrophil 1.19 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.51 mmol/L.
- Day 348 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 2.44 ×10⁹/L; Absolute Neutrophil 1.12 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 4.02 mmol/L.
- Day 541 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 7.75 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.34 ×10⁹/L; Absolute Neutrophil 0.84 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.57 mmol/L.
- Day 583: Creatinine 116 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.07 mmol/L.
- Day 716 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Immunoglobulin G 8.55 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.83 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 3.58 mmol/L.
- Day 919 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.36 mg/dL; Hemoglobin 7.5 mmol/L; Leukocytes 2.98 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 4.9 mmol/L.
- Day 1,010: Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.44 mg/dL; Hemoglobin 7.63 mmol/L; Leukocytes 2.01 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.99 mmol/L.
- Day 1,101 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.71 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 3.18 ×10⁹/L; Absolute Neutrophil 1.41 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 4.46 mmol/L.
- Day 1,120 (ECOG 0): Hemoglobin 7.87 mmol/L; Leukocytes 4.04 ×10⁹/L; Absolute Neutrophil 1.93 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.
- Day 1,195 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.1 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.53 ×10⁹/L; Absolute Neutrophil 2.24 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 9.19 mmol/L.

Other clinical attributes
- Day -30: Weight: 66 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1672_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -30 days.
- Sample MMRF_1672_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -30 days.
